Gene-level copy-number profile of tumor specimen TCGA-60-2696-01A from TCGA case TCGA-60-2696, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.6 years (27,991 days).
Specimen TCGA-60-2696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.89f4468f-1309-487e-ada9-207ef2301874.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2696-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1633c05a-869e-4401-b0e5-70b1cac37262

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 19,569; copy number 2: 37,738; copy number 3: 2,487; copy number 4: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-60-2696-01): tumor purity 0.42, ploidy 1.72, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:2,421,597–2,660,056, 3 genes (within-gene range 0–1): VLDLR-AS1, AL353614.1, VLDLR.
- chr18:59,899,996–60,301,317, 13 genes: PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P, AC090771.2, RPS3AP49, RNU4-17P, AC090771.1, AC090621.1.
- chr18:60,371,062–60,372,775, 1 gene: MC4R.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 17,148. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
